CPTAC case 01BR043 — Breast — Adenomas and Adenocarcinomas (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/59b8a334-51b4-46f6-868d-c420aaa0eafb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/33; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 59.5 years (21,747 days); AJCC pathologic stage: Stage II; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 99a3ae40-47ba-43af-a290-19619b: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample c4015b28-269b-4dc4-8b2e-1b83f7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
